Somatic mutation profile of cancer-model specimen HCM-BROD-0116-C16-85B (3D Organoid, passage 4; aliquot HCM-BROD-0116-C16-85B-01D-A79C-36), derived from the primary tumor of HCMI case HCM-BROD-0116-C16, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IIIB; Tumor grade: G3; Age at diagnosis: 56.7 years (20,721 days).
Specimen HCM-BROD-0116-C16-85B: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 4.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7de08279-af31-402f-9cbc-f48344abd686.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0116-C16-10B (Blood Derived Normal), aliquot HCM-BROD-0116-C16-10B-01D-A79C-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3e9d0b43-ad88-465d-ad06-8a186066de2a

The open-access MAF lists 119 somatic variants for this specimen: 88 protein-altering or splice-affecting, 30 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 76, Silent 30, Frame Shift Del 4, Nonsense Mutation 3, Translation Start Site 2, Frame Shift Ins 2, Intron 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CNOT9 | c.259T>C p.S87P | Missense Mutation (SNP) | VAF 155/247 reads (63%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as rs1057519956, COSV55299564; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- NF1 | c.1318C>T p.R440* | Nonsense Mutation (SNP) | VAF 77/298 reads (26%) | hotspot (GDC flag); catalogued as rs778405030, CM950845, COSV62197118; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.193A>T p.R65* | Nonsense Mutation (SNP) | VAF 342/344 reads (99%) | catalogued as rs1555526721, COSV52689560; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ANKRD30B | c.439G>A p.V147I | Missense Mutation (SNP) | VAF 178/436 reads (41%) | SIFT tolerated (0.12); PolyPhen benign (0.021); catalogued as rs752127097, COSV62814186, COSV62825406; called by muse, mutect2
- ATIC | c.1669G>C p.A557P | Missense Mutation (SNP) | VAF 75/247 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.146); catalogued as COSV99378238; called by muse, mutect2, varscan2
- BAZ1B | c.2864G>A p.R955H | Missense Mutation (SNP) | VAF 130/284 reads (46%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.474); catalogued as rs1310053804, COSV59994327; called by muse, mutect2, varscan2
- BECN2 | c.500G>A p.R167Q | Missense Mutation (SNP) | VAF 338/725 reads (47%) | SIFT tolerated (0.31); PolyPhen benign (0.218); catalogued as rs755412110; called by muse, mutect2
- CTDSPL2 | c.149C>G p.S50C | Missense Mutation (SNP) | VAF 316/316 reads (100%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.781); catalogued as COSV52945306; called by muse, mutect2, varscan2
- DACH2 | c.1352G>T p.S451I | Missense Mutation (SNP) | VAF 182/182 reads (100%) | SIFT deleterious (0); PolyPhen possibly damaging (0.559); catalogued as COSV100912689; called by muse, mutect2, varscan2
- DNAH7 | c.5798T>C p.L1933S | Missense Mutation (SNP) | VAF 52/189 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV56781724; called by muse, mutect2, varscan2
- DTNA | c.91C>T p.R31* | Nonsense Mutation (SNP) | VAF 134/137 reads (98%) | catalogued as rs1320555032, COSV51994365; called by muse, mutect2, varscan2
- EGFLAM | c.2398C>T p.R800W | Missense Mutation (SNP) | VAF 212/721 reads (29%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.895); catalogued as rs200790571, COSV59303445, COSV59310220; called by muse, mutect2, varscan2
- ERICH3 | c.197G>A p.R66Q | Missense Mutation (SNP) | VAF 115/201 reads (57%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as rs758189061, COSV58610769; called by muse, mutect2, varscan2
- ERN1 | c.1903C>T p.R635W | Missense Mutation (SNP) | VAF 104/426 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as rs146710304; called by muse, mutect2, varscan2
- FAM53A | c.482G>A p.R161Q | Missense Mutation (SNP) | VAF 199/637 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.129); catalogued as rs759308454, COSV57400613; called by muse, mutect2, varscan2
- GOLGA8O | c.266C>T p.T89M | Missense Mutation (SNP) | VAF 38/248 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.589); catalogued as rs1199647386; called by muse, mutect2, varscan2
- HPS5 | c.1591C>T p.R531C (on ENST00000349215 / NM_181507.2; = p.R417C on NM_007216.4) | Missense Mutation (SNP) | VAF 52/246 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.943); catalogued as COSV61687889; called by muse, mutect2, varscan2
- MYH7B | c.532G>A p.V178I | Missense Mutation (SNP) | VAF 256/676 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.312); catalogued as rs370219232; called by muse, mutect2, varscan2
- NLRP9 | c.1783C>T p.R595C | Missense Mutation (SNP) | VAF 161/351 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as rs143466064, COSV60463338; called by muse, mutect2, varscan2
- OR52E8 | c.716G>A p.R239Q | Missense Mutation (SNP) | VAF 151/349 reads (43%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.499); catalogued as rs753679630, COSV66206802; called by muse, mutect2, varscan2
- PANK4 | c.2110C>T p.R704C | Missense Mutation (SNP) | VAF 166/341 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1279771228; called by muse, mutect2, varscan2
- PCLO | c.12179C>T p.A4060V | Missense Mutation (SNP) | VAF 246/498 reads (49%) | SIFT deleterious (0.03); PolyPhen benign (0.254); catalogued as rs370449283, COSV61659259; called by muse, mutect2, varscan2
- PER2 | c.3562C>T p.R1188C | Missense Mutation (SNP) | VAF 104/352 reads (30%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as rs748810685, COSV54521568; called by muse, mutect2, varscan2
- PLK1 | c.1588G>A p.V530M | Missense Mutation (SNP) | VAF 92/456 reads (20%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.73); catalogued as rs140033760; called by muse, mutect2, varscan2
- PSMD7 | c.834_836del p.N278del | In Frame Del (DEL) | VAF 128/667 reads (19%) | catalogued as rs1412019340; called by pindel, varscan2
- PTPN6 | c.553G>A p.D185N | Missense Mutation (SNP) | VAF 104/405 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.155); catalogued as rs782079530, COSV59684395; called by muse, mutect2, varscan2
- ROPN1 | c.352G>A p.E118K | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.988); catalogued as rs750925930; called by mutect2, varscan2
- SETBP1 | c.3233C>T p.T1078M | Missense Mutation (SNP) | VAF 135/279 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.522); catalogued as rs375939479; called by muse, mutect2, varscan2
- SMAD7 | c.908C>T p.S303L | Missense Mutation (SNP) | VAF 264/271 reads (97%) | SIFT tolerated (0.3); PolyPhen benign (0.07); catalogued as rs1271258535; called by muse, mutect2, varscan2
- STARD9 | c.11827G>T p.A3943S | Missense Mutation (SNP) | VAF 123/471 reads (26%) | SIFT tolerated (0.54); PolyPhen benign (0.03); catalogued as rs1362715115; called by muse, mutect2, varscan2
- STRA8 | c.896G>A p.C299Y (on ENST00000275764; = p.C277Y on NM_182489.2) | Missense Mutation (SNP) | VAF 67/256 reads (26%) | SIFT tolerated (0.17); PolyPhen benign (0.031); catalogued as rs1363088441; called by muse, mutect2, varscan2
- TAF11L13 | c.412G>A p.A138T | Missense Mutation (SNP) | VAF 240/802 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs186785660; called by muse, mutect2, varscan2
- TEKT3 | c.1450C>T p.L484F | Missense Mutation (SNP) | VAF 147/147 reads (100%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.615); catalogued as rs1398296925; called by muse, mutect2, varscan2
- THBS1 | c.2705G>A p.G902D | Missense Mutation (SNP) | VAF 128/454 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1393596775; called by muse, mutect2, varscan2
- TNNT1 | c.316C>T p.R106C | Missense Mutation (SNP) | VAF 166/335 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99402997; called by muse, mutect2, varscan2
- TRIM64B | c.152G>A p.R51H | Missense Mutation (SNP) | VAF 212/1019 reads (21%) | SIFT tolerated (0.58); PolyPhen benign (0.007); catalogued as rs1238275261, COSV61693771; called by muse, varscan2
- TYR | c.895C>T p.R299C | Missense Mutation (SNP) | VAF 171/367 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs61754374, CM091272, CM971547; called by muse, mutect2, varscan2
- UBN1 | c.733G>A p.V245I | Missense Mutation (SNP) | VAF 137/463 reads (30%) | SIFT tolerated (0.21); PolyPhen benign (0.012); catalogued as rs1220448818; called by muse, mutect2, varscan2
- UNC79 | c.5048C>T p.P1683L (on ENST00000393151 / NM_001346218.2; = p.P1506L on NM_020818.5) | Missense Mutation (SNP) | VAF 354/357 reads (99%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.104); catalogued as rs757073570, COSV56375700, COSV56414071; called by muse, mutect2, varscan2
- WEE2 | c.53A>G p.Y18C | Missense Mutation (SNP) | VAF 123/530 reads (23%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs1563010910; called by muse, mutect2, varscan2
- ZNF883 | c.938G>A p.R313K | Missense Mutation (SNP) | VAF 194/430 reads (45%) | SIFT tolerated (0.17); PolyPhen benign (0.033); catalogued as rs752559120; called by muse, mutect2, varscan2
- ACAT1 | c.1039_1045del p.I347Cfs*4 | Frame Shift Del (DEL) | VAF 41/184 reads (22%) | called by mutect2, pindel, varscan2
- ADGB | c.1725A>C p.Q575H | Missense Mutation (SNP) | VAF 36/127 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.626); called by muse, mutect2, varscan2
- ARID1A | c.964_988del p.D322Rfs*33 | Frame Shift Del (DEL) | VAF 256/318 reads (81%) | called by pindel, varscan2
- ATP10D | c.3359A>C p.K1120T | Missense Mutation (SNP) | VAF 65/162 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ATP2A1 | c.1318G>T p.A440S | Missense Mutation (SNP) | VAF 166/378 reads (44%) | SIFT tolerated (0.23); PolyPhen benign (0.112); called by muse, mutect2, varscan2
- BTBD2 | c.1199_1200dup p.I401Afs*21 | Frame Shift Ins (INS) | VAF 248/473 reads (52%) | called by mutect2, pindel, varscan2
- CCDC168 | c.20789dup p.N6930Kfs*20 | Frame Shift Ins (INS) | VAF 66/264 reads (25%) | called by mutect2, pindel, varscan2
- CFAP70 | c.1047G>T p.L349F | Missense Mutation (SNP) | VAF 107/455 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CNOT3 | c.1126G>T p.A376S | Missense Mutation (SNP) | VAF 312/1119 reads (28%) | SIFT tolerated (0.26); PolyPhen benign (0.111); called by muse, mutect2, varscan2
- D2HGDH | c.157C>G p.P53A | Missense Mutation (SNP) | VAF 178/770 reads (23%) | SIFT tolerated (0.05); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- DISP3 | c.1858C>A p.L620M | Missense Mutation (SNP) | VAF 31/318 reads (10%) | SIFT tolerated (0.37); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- EML5 | c.3701A>G p.Y1234C | Missense Mutation (SNP) | VAF 153/153 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GABRB1 | c.469A>C p.T157P | Missense Mutation (SNP) | VAF 67/239 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2
- HBE1 | c.175C>T p.P59S | Missense Mutation (SNP) | VAF 140/278 reads (50%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KANK3 | c.1532G>T p.G511V | Missense Mutation (SNP) | VAF 228/643 reads (35%) | SIFT tolerated (0.27); PolyPhen benign (0.381); called by mutect2, varscan2
- KCNQ5 | c.1212C>A p.S404R | Missense Mutation (SNP) | VAF 79/187 reads (42%) | SIFT tolerated (0.32); PolyPhen benign (0.254); called by muse, mutect2, varscan2
- KHDRBS2 | c.307G>A p.G103S | Missense Mutation (SNP) | VAF 65/144 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KRTAP4-5 | c.212G>C p.C71S | Missense Mutation (SNP) | VAF 424/915 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- LRRK2 | c.6967A>C p.I2323L | Missense Mutation (SNP) | VAF 178/383 reads (46%) | SIFT tolerated (0.11); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MEI4 | c.194T>G p.L65R | Missense Mutation (SNP) | VAF 77/181 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); called by muse, mutect2, varscan2
- MITD1 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 155/223 reads (70%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.112); called by muse, mutect2, varscan2
- NR3C2 | c.826C>G p.P276A | Missense Mutation (SNP) | VAF 136/416 reads (33%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.416); called by muse, mutect2, varscan2
- OPA1 | c.1460T>G p.I487S (on ENST00000361510 / NM_130837.3; = p.I432S on NM_015560.3) | Missense Mutation (SNP) | VAF 112/252 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR2L2 | c.808G>A p.D270N | Missense Mutation (SNP) | VAF 165/374 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.232); called by muse, mutect2
- OR4K5 | c.467C>T p.T156I | Missense Mutation (SNP) | VAF 157/348 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.151); called by muse, mutect2, varscan2
- OR4L1 | c.356C>A p.A119D | Missense Mutation (SNP) | VAF 115/238 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- PBRM1 | c.3846del p.V1283Wfs*2 (on ENST00000296302 / NM_001366071.2; = p.V1258Wfs*2 on NM_018313.5) | Frame Shift Del (DEL) | VAF 192/267 reads (72%) | called by mutect2, pindel, varscan2
- PRRX2 | c.264G>T p.E88D | Missense Mutation (SNP) | VAF 255/530 reads (48%) | SIFT tolerated (0.61); PolyPhen benign (0); called by muse, mutect2, varscan2
- RAB3GAP2 | c.2485A>T p.I829F | Missense Mutation (SNP) | VAF 112/461 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.312); called by muse, mutect2, varscan2
- SCAPER | c.2408C>T p.S803L | Missense Mutation (SNP) | VAF 56/210 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.764); called by muse, mutect2, varscan2
- SF3B1 | c.3080G>A p.R1027K | Missense Mutation (SNP) | VAF 147/222 reads (66%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SF3B6 | c.21G>T p.K7N | Missense Mutation (SNP) | VAF 128/410 reads (31%) | SIFT tolerated (0.2); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SMG1 | c.8194G>A p.A2732T | Missense Mutation (SNP) | VAF 146/532 reads (27%) | SIFT tolerated (0.27); PolyPhen benign (0.259); called by muse, mutect2, varscan2
- SMOC2 | c.1318A>G p.R440G (on ENST00000356284 / NM_001166412.2; = p.R451G on NM_022138.3) | Missense Mutation (SNP) | VAF 61/159 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- SOST | c.397C>T p.R133C | Missense Mutation (SNP) | VAF 224/987 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SUGT1 | c.310G>A p.E104K | Missense Mutation (SNP) | VAF 84/137 reads (61%) | SIFT tolerated (0.14); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- TBC1D10A | c.1142G>C p.C381S | Missense Mutation (SNP) | VAF 412/887 reads (46%) | SIFT tolerated (0.37); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TBKBP1 | c.776G>A p.G259E | Missense Mutation (SNP) | VAF 183/728 reads (25%) | SIFT tolerated (0.79); PolyPhen benign (0); called by muse, mutect2, varscan2
- THSD7A | c.426del p.K142Nfs*14 | Frame Shift Del (DEL) | VAF 230/554 reads (42%) | called by mutect2, pindel, varscan2
- TLE4 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 271/418 reads (65%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0); called by muse, mutect2, varscan2
- TSPYL4 | c.71C>T p.A24V | Missense Mutation (SNP) | VAF 150/360 reads (42%) | SIFT tolerated (0.22); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TTN | c.2654A>C p.D885A (on ENST00000591111; = p.D839A on NM_003319.4) | Missense Mutation (SNP) | VAF 125/386 reads (32%) | PolyPhen benign (0.098); called by muse, mutect2, varscan2
- UVRAG | c.744G>C p.Q248H | Missense Mutation (SNP) | VAF 72/367 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- XYLT1 | c.532C>G p.Q178E | Missense Mutation (SNP) | VAF 215/477 reads (45%) | SIFT tolerated, low confidence (0.74); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- ZIC1 | c.185C>T p.T62M | Missense Mutation (SNP) | VAF 228/935 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.587); called by muse, mutect2, varscan2
- ZNF14 | c.832C>A p.P278T | Missense Mutation (SNP) | VAF 138/438 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- ZNF544 | c.647A>C p.H216P | Missense Mutation (SNP) | VAF 92/414 reads (22%) | SIFT tolerated (0.17); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ABCA3 | c.3138G>A p.A1046= | Silent (SNP) | VAF 333/716 reads (47%) | catalogued as rs764759666, COSV57057605; called by muse, varscan2
- ANTKMT | c.342G>A p.A114= | Silent (SNP) | VAF 223/753 reads (30%) | catalogued as rs745533194; called by muse, mutect2, varscan2
- ARID5B | c.3318G>A p.L1106= | Silent (SNP) | VAF 173/359 reads (48%) | called by muse, mutect2, varscan2
- CCDC116 | c.990C>T p.R330= | Silent (SNP) | VAF 394/816 reads (48%) | catalogued as rs768637483, COSV53037200; called by muse, mutect2, varscan2
- DCAF5 | c.147C>T p.L49= | Silent (SNP) | VAF 16/418 reads (4%) | catalogued as rs1254859645, COSV58460945; called by muse, mutect2
- DSEL | c.3087T>G p.V1029= | Silent (SNP) | VAF 141/296 reads (48%) | called by muse, mutect2, varscan2
- EIF1 | c.135T>C p.T45= | Silent (SNP) | VAF 23/454 reads (5%) | catalogued as rs1407402470, COSV60422169; called by muse, mutect2
- ENDOU | c.261C>A p.P87= (on ENST00000422538 / NM_001172439.2; = p.P46= on NM_006025.4) | Silent (SNP) | VAF 154/332 reads (46%) | called by muse, mutect2, varscan2
- ENOX1 | c.201C>T p.L67= | Silent (SNP) | VAF 60/204 reads (29%) | catalogued as rs764324372, COSV54893239; called by muse, mutect2, varscan2
- GFRA2 | c.561C>T p.R187= | Silent (SNP) | VAF 292/638 reads (46%) | catalogued as rs375577535; called by muse, mutect2, varscan2
- HIC1 | c.246C>A p.L82= (on ENST00000322941 / NM_001098202.1; = p.L63= on NM_006497.4) | Silent (SNP) | VAF 14/416 reads (3%) | catalogued as COSV53964464; called by muse, mutect2
- INSC | c.384T>C p.G128= | Silent (SNP) | VAF 302/630 reads (48%) | called by muse, mutect2, varscan2
- LETM1 | c.1950C>A p.V650= | Silent (SNP) | VAF 78/298 reads (26%) | catalogued as COSV57105658; called by muse, mutect2, varscan2
- NANOG | c.843T>C p.T281= | Silent (SNP) | VAF 94/358 reads (26%) | catalogued as rs1391412144; called by muse, mutect2, varscan2
- NEURL1 | c.183G>A p.T61= | Silent (SNP) | VAF 324/328 reads (99%) | called by muse, mutect2, varscan2
- NOVA1 | c.738A>G p.Q246= | Silent (SNP) | VAF 9/201 reads (4%) | catalogued as COSV57471682, COSV57474978; called by muse, mutect2
- OR2L3 | c.636T>A p.A212= | Silent (SNP) | VAF 230/482 reads (48%) | called by muse, varscan2
- PARP1 | c.2265A>C p.A755= | Silent (SNP) | VAF 80/287 reads (28%) | called by muse, mutect2, varscan2
- PCNX2 | c.3507G>A p.R1169= | Silent (SNP) | VAF 122/250 reads (49%) | called by muse, mutect2
- PRPF4 | c.144G>A p.G48= (on ENST00000374198 / NM_001322267.2; = p.G49= on NM_004697.5) | Silent (SNP) | VAF 91/407 reads (22%) | called by muse, mutect2, varscan2
- RFX2 | c.1077C>T p.D359= | Silent (SNP) | VAF 267/428 reads (62%) | catalogued as rs766680124; called by muse, mutect2, varscan2
- RHOXF1 | c.174C>T p.N58= | Silent (SNP) | VAF 221/496 reads (45%) | catalogued as rs781952489, COSV54294144, COSV99483761; called by muse, mutect2, varscan2
- SCN1A | c.777C>T p.S259= | Silent (SNP) | VAF 67/187 reads (36%) | catalogued as rs121918735, CM104863; called by muse, mutect2, varscan2
- SIX3 | c.288T>C p.C96= | Silent (SNP) | VAF 23/586 reads (4%) | catalogued as COSV53227290; called by muse, mutect2
- TEX14 | c.1878C>T p.F626= (on ENST00000240361 / NM_001201457.2; = p.F620= on NM_031272.5) | Silent (SNP) | VAF 247/496 reads (50%) | catalogued as rs374631413; called by muse, mutect2, varscan2
- THEM6 | c.162G>A p.V54= | Silent (SNP) | VAF 601/1203 reads (50%) | called by muse, mutect2, varscan2
- TRIM42 | c.1791C>T p.N597= | Silent (SNP) | VAF 229/451 reads (51%) | catalogued as rs1021590216, COSV53887584; called by muse, mutect2, varscan2
- TRPC1 | c.576C>A p.G192= (on ENST00000476941 / NM_001251845.2; = p.G158= on NM_003304.4) | Silent (SNP) | VAF 188/398 reads (47%) | called by muse, mutect2, varscan2
- UBTFL1 | c.354C>T p.Y118= | Silent (SNP) | VAF 173/245 reads (71%) | called by muse, mutect2, varscan2
- UTRN | c.3000A>G p.L1000= | Silent (SNP) | VAF 40/180 reads (22%) | called by muse, mutect2, varscan2
- NRG1 | c.502+31210C>T | Intron (SNP) | VAF 234/506 reads (46%) | catalogued as rs771642512, COSV55154917; called by muse, mutect2, varscan2
